Somatic mutation profile of tumor specimen 0DFYQO from CCDI case PBBSVB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 15.2 years (5,544 days).
Specimen 0DFYQO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b345836-bca3-43bb-8c27-4525cb61a595.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFYPF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16e2a68a-8b3d-42cc-80aa-bf2d20881add

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.2602C>A p.Q868K (on ENST00000297405 / NM_001363185.1; = p.Q764K on NM_052900.3) | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52271738; called by mutect2, varscan2
- HNRNPM | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 123/345 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as COSV55314676, COSV99725922; called by muse, mutect2, varscan2
- LRRC4B | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); catalogued as COSV65350697; called by muse, mutect2, varscan2
- SH3TC2 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs771002048; called by muse, mutect2, varscan2
- TOX | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 345/632 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63848324; called by muse, mutect2, varscan2
- BZW1 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 278/586 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- TSPOAP1 | c.2552G>A p.W851* | Nonsense Mutation (SNP) | VAF 121/338 reads (36%) | called by muse, mutect2, varscan2
- FAM47A | c.1152G>A p.V384= | Silent (SNP) | VAF 147/209 reads (70%) | called by muse, mutect2, varscan2
- FAM83D | c.696G>A p.R232= | Silent (SNP) | VAF 175/620 reads (28%) | called by muse, varscan2
- OR2AG2 | c.543C>T p.I181= | Silent (SNP) | VAF 231/321 reads (72%) | called by muse, mutect2, varscan2
- PTH2 | c.-96G>A | 5'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, varscan2
- TGIF2LY | c.-22+47T>C | Intron (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2
